Gene-level copy-number profile of tumor specimen ALCH-B4AR-TTP1-A from ALCHEMIST case ALCH-B4AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 67.6 years (24,679 days).
Specimen ALCH-B4AR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39dd9b5e-8a4e-4c6a-8b6c-31f2665daef5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4AR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/e1174989-b7b2-4016-9cfa-68caab83b469

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 2,247; copy number 2: 55,599; copy number 3: 407; copy number 4: 37; copy number 5: 5; copy number 6: 6; copy number 7: 1; copy number 9: 1; copy number 10: 2; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,366,656–53,368,245, 1 gene: LINC02812.
- chr2:132,285,795–132,294,377, 1 gene: AC097532.1.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr3:48,636,463–48,669,174, 3 genes (within-gene range 0–2): CELSR3, MIR4793, LINC02585.
- chr5:55,219,564–55,233,608, 2 genes: MCIDAS, CCNO.
- chr5:134,081,914–134,082,040, 1 gene: AC008608.1.
- chr7:74,964,705–75,074,228, 3 genes: CASTOR2, RCC1L, Metazoa_SRP.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:124,853,417–124,857,890, 1 gene (within-gene range 0–2): WDR38.
- chr10:49,771,841–49,773,299, 1 gene: MAPK6P6.
- chr11:47,177,522–47,191,542, 3 genes: PACSIN3, MIR6745, AC090589.1.
- chr11:71,428,193–71,452,868, 2 genes: DHCR7, AP002387.1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:20,365,667–20,413,501, 1 gene: TEP1.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.
- chr15:25,215,541–25,250,940, 20 genes (within-gene range 0–2): SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:47,359,430–47,396,732, 1 gene (within-gene range 0–2): AC023905.1.
- chr15:57,300,365–57,307,769, 1 gene: LINC00926.
- chr15:75,676,227–75,680,752, 2 genes (within-gene range 0–1): AC105020.4, AC105020.1.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:61,361,668–61,400,243, 2 genes (within-gene range 0–2): AC005746.2, AC005746.1.
- chr17:77,396,984–77,397,054, 1 gene (within-gene range 0–2): MIR4316.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–2): AC090386.2.
- chr21:44,158,740–44,194,338, 3 genes: LINC01678, AP001056.2, AP001056.1.
- chr22:23,510,154–23,513,602, 2 genes: AP000345.3, LINC02557.
- chr22:36,071,000–36,093,352, 2 genes: Z95114.1, Z95114.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:170,105,897–170,141,940, 2 genes, copy number 6: FOXI1, KRT18P41.
- chr5:170,232,447–170,335,508, 4 genes, copy number 6 (within-gene range 4–6): C5orf58, LCP2, LINC01366, AC034199.1.
- chr6:33,291,654–33,298,942, 1 gene, copy number 9: RGL2.
- chr7:75,391,955–75,416,787, 3 genes, copy number 10–21 (within-gene range 2–21): AC211486.1, TRIM73, NSUN5P1.
- chr10:46,109,621–46,131,358, 1 gene, copy number 5: AGAP7P.
- chr19:1,275,530–1,279,244, 1 gene, copy number 5: FAM174C.
- chr21:43,414,483–43,453,902, 2 genes, copy number 5–7: SIK1, LINC00319.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 0–5): GATD3A.
- chr21:44,217,014–44,240,966, 1 gene, copy number 5: ICOSLG.

Autosomal genes at a single copy (total copy number 1): 2,247. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
